Surgical pathology report (de-identified scan), TCGA case TCGA-05-4430, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Indivumed, specimen TCGA-05-4430-01A (Primary Tumor).

Main diagnosis/diagnoses:

Peripheral bronchopulmonary, histologically mixed-cell adenocarcinoma of the left lower lobe of the lung with a predominant acinar and small large-cell solid component, a bronchioloalveolar pattern of spread in the tumor periphery and main localization in S6. TNM classification on the basis of this material pT2 pN0 pMX R0, stage IB. C34.3; M 8255/3.

Comment/supplementary remark:

The carcinoma has infiltrated the visceral pleura. The resection margin of the bronchus and vessels and all the lymph nodes removed are tumor-free.

Source: NCI Genomic Data Commons file 7b738dd3-5a70-42e9-9270-43228cbb6b28 (TCGA-05-4430.0C8A524E-3241-4CDE-8D22-1330AAF8C603.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).